Somatic mutation profile of tumor specimen TCGA-B6-A0IJ-01A (aliquot TCGA-B6-A0IJ-01A-11W-A050-09) from TCGA case TCGA-B6-A0IJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 42.8 years (15,625 days).
Specimen TCGA-B6-A0IJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1970a22-abac-4274-af6d-b16796b40679.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0IJ-10A (Blood Derived Normal), aliquot TCGA-B6-A0IJ-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca6c5a9e-46cb-4caf-803e-6788f4ab67d4

The open-access MAF lists 147 somatic variants for this specimen: 123 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 22, Nonsense Mutation 8, Splice Site 3, In Frame Del 2, Intron 1, Frame Shift Del 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MECP2 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs1064797047, COSV57651600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.8136dup p.D2713Rfs*10 | Frame Shift Ins (INS) | VAF 3/31 reads (10%) | catalogued as rs761483896; ClinVar: pathogenic; called by pindel, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 117/271 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5096C>A p.S1699Y (on ENST00000272895 / NM_173076.3; = p.S1381Y on NM_015657.3) | Missense Mutation (SNP) | VAF 69/291 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as rs767287642, COSV55961180; called by muse, mutect2, varscan2
- ABCB1 | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55952778; called by muse, mutect2, varscan2
- ADAM30 | c.364T>G p.S122A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV101023786; called by mutect2, varscan2
- ANKRD6 | c.1475del p.E492Gfs*11 | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | catalogued as COSV60232033; called by mutect2, pindel, varscan2
- APEX2 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV100895162; called by muse, mutect2, varscan2
- ARID3C | c.979G>C p.G327R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as COSV99426791; called by muse, mutect2
- ASZ1 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52913203; called by muse, mutect2, varscan2
- BANK1 | c.2213A>G p.N738S | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV59843583; called by muse, mutect2, varscan2
- BTN3A2 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100709592, COSV62687600; called by muse, mutect2
- BZW1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.293); catalogued as COSV63349771; called by muse, mutect2, varscan2
- CATSPERE | c.1084G>T p.G362* | Nonsense Mutation (SNP) | VAF 20/222 reads (9%) | catalogued as COSV100834972; called by muse, mutect2
- CCDC198 | c.617T>C p.L206P | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV53602256; called by muse, mutect2, varscan2
- CDHR2 | c.3427A>G p.S1143G | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV56139742; called by muse, mutect2, varscan2
- CDHR2 | c.3428G>C p.S1143T | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV56139754; called by muse, mutect2, varscan2
- CHD4 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV58902236; called by muse, mutect2, varscan2
- CLEC1A | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59532360; called by muse, mutect2, varscan2
- COG4 | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs772560552, COSV55371496; called by muse, mutect2, varscan2
- CYP4F11 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs771510465, COSV56125612; called by muse, mutect2, varscan2
- DENND2A | c.1337C>G p.T446S | Missense Mutation (SNP) | VAF 15/235 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99325693; called by muse, mutect2
- DNAH7 | c.707A>T p.D236V | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV56767556; called by muse, mutect2, varscan2
- DNAH9 | c.8035C>T p.L2679F | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52352702; called by muse, mutect2, varscan2
- DOCK5 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs1381001934, COSV52403216; called by muse, mutect2, varscan2
- DROSHA | c.545T>C p.F182S | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.91); catalogued as COSV60776998; called by muse, mutect2, varscan2
- EML4 | c.2908C>A p.L970I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV59299100; called by muse, varscan2
- EPC1 | c.1152+1G>T p.X384_splice | Splice Site (SNP) | VAF 14/121 reads (12%) | catalogued as COSV53926259; called by muse, mutect2, varscan2
- EQTN | c.422C>A p.A141D | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66218147; called by muse, mutect2, varscan2
- EYA3 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as COSV65816812; called by muse, mutect2, varscan2
- FILIP1 | c.2128T>C p.F710L | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52731559; called by muse, mutect2, varscan2
- FRAS1 | c.4089A>C p.E1363D | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV53615347; called by muse, mutect2, varscan2
- GOLGA5 | c.804G>C p.K268N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as rs1168971513, COSV50833300; called by muse, mutect2, varscan2
- GPLD1 | c.258C>A p.S86R | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV57757840; called by muse, mutect2, varscan2
- GRIN2A | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV58030715, COSV58035978; called by muse, mutect2, varscan2
- HACD2 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 28/644 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as COSV67323554; called by muse, mutect2
- HAUS4 | c.688A>G p.K230E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV99246787; called by muse, mutect2, varscan2
- HEG1 | c.1942G>T p.V648F | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60762701; called by muse, mutect2, varscan2
- HFM1 | c.2428G>T p.V810F | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV54028471; called by muse, mutect2, varscan2
- HIVEP1 | c.2372C>G p.S791C | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65102097; called by muse, mutect2, varscan2
- HSPB3 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.261); catalogued as rs1273784465, COSV57357084; called by muse, mutect2, varscan2
- HTR1E | c.515A>T p.Q172L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV59508411; called by muse, mutect2, varscan2
- HYDIN | c.7055G>A p.R2352Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs779284526, COSV59258663; called by mutect2, varscan2
- IFNA14 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV66516187; called by muse, mutect2, varscan2
- IGLV1-40 | c.134G>C p.S45T | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); catalogued as rs143677402; called by muse, mutect2, varscan2
- IL4R | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50145973; called by muse, mutect2, varscan2
- ILVBL | c.1088T>A p.V363D | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV54619997; called by muse, mutect2, varscan2
- KIAA0319 | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV65496218, COSV65498817; called by muse, mutect2, varscan2
- KLF7 | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV58744020; called by muse, mutect2, varscan2
- KMT2C | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51446263; called by muse, mutect2, varscan2
- LMO4 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV100983970; called by muse, mutect2
- LMTK2 | c.2612C>G p.S871* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs1444596326, COSV51996871; called by muse, mutect2, varscan2
- LONRF1 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1314982172, COSV68036962; called by muse, mutect2, varscan2
- MC2R | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as CM057714, COSV59618391, COSV59619695; called by muse, mutect2, varscan2
- MDP1 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51660570; called by muse, mutect2, varscan2
- MORC1 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 166/559 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51721253; called by muse, mutect2, varscan2
- MRPS31 | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100062072; called by muse, mutect2, varscan2
- MYH4 | c.3733G>T p.A1245S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV55119217; called by muse, mutect2, varscan2
- MYO10 | c.4407C>G p.Y1469* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as COSV57016563, COSV57022599; called by muse, mutect2, varscan2
- NCKAP5 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58447015, COSV58474004; called by muse, mutect2, varscan2
- NDC80 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV55248286; called by muse, mutect2, varscan2
- NLRP2 | c.2880-1G>A p.X960_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as COSV99672001; called by muse, mutect2
- NOTCH3 | c.5713G>C p.D1905H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764558842, COSV54636533; called by muse, mutect2, varscan2
- OR14A16 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs893606356, COSV100713715, COSV62926846; called by muse, mutect2
- OR14I1 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as COSV61199746; called by muse, mutect2, varscan2
- OR4X2 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV56583532; called by muse, mutect2, varscan2
- OR52A5 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); catalogued as rs142969856; called by muse, mutect2, varscan2
- PARP1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.566); catalogued as COSV100828505; called by muse, mutect2
- PCED1B | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as COSV71395266; called by muse, mutect2, varscan2
- PDCD4 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 9/293 reads (3%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV99700821; called by muse, mutect2
- PLCZ1 | c.1603A>T p.R535* | Nonsense Mutation (SNP) | VAF 24/155 reads (15%) | catalogued as COSV56853336; called by muse, mutect2, varscan2
- PLEKHG2 | c.2905C>A p.L969I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV52684529; called by muse, mutect2, varscan2
- PLXNA2 | c.777G>C p.Q259H | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65441288; called by muse, mutect2, varscan2
- PM20D2 | c.578A>G p.E193G | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.636); catalogued as COSV51530772; called by muse, mutect2, varscan2
- PPP1R15B | c.1341T>A p.D447E | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.693); catalogued as COSV65815836, COSV65816703; called by muse, mutect2, varscan2
- PRB3 | c.883C>T p.Q295* (on ENST00000381842; = p.Q337* on NM_006249.5) | Nonsense Mutation (SNP) | VAF 186/598 reads (31%) | catalogued as COSV54390613; called by muse, mutect2, varscan2
- PREX2 | c.3621G>C p.K1207N | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV55774160; called by muse, mutect2, varscan2
- PRKAA2 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100982839, COSV64804139; called by muse, mutect2, varscan2
- PSG11 | c.106G>T p.V36F | Missense Mutation (SNP) | VAF 167/309 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV60455538; called by muse, mutect2, varscan2
- PXDNL | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs776904737, COSV62477807; called by muse, mutect2, varscan2
- RAB40AL | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99505030; called by muse, mutect2
- RBMX | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV100284609; called by muse, mutect2
- RHEX | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV58980605, COSV58982095; called by muse, mutect2, varscan2
- RPL41 | c.62G>C p.R21T | Missense Mutation (SNP) | VAF 59/124 reads (48%) | catalogued as COSV57568888; called by muse, mutect2, varscan2
- RTL6 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV57979662; called by muse, mutect2, varscan2
- RTL8A | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV66188316; called by muse, mutect2, varscan2
- SCN10A | c.3319G>C p.D1107H | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV71861707; called by muse, mutect2, varscan2
- SDK2 | c.4806C>A p.Y1602* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV66187154; called by muse, mutect2, varscan2
- SLC15A1 | c.1774A>T p.T592S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs1274555633, COSV64731796; called by muse, mutect2, varscan2
- SLC22A25 | c.914G>A p.R305K | Missense Mutation (SNP) | VAF 136/387 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as COSV60595232, COSV60596373; called by muse, mutect2, varscan2
- SLC39A6 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as COSV52369525, COSV99309444, COSV99309873; called by muse, mutect2, varscan2
- SLC45A2 | c.428G>A p.S143N | Missense Mutation (SNP) | VAF 81/336 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs1436295745, COSV56872362; called by muse, mutect2, varscan2
- SLC4A8 | c.681G>T p.K227N | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV60653339; called by muse, mutect2, varscan2
- SLFN5 | c.2040G>C p.W680C | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs1385753967, COSV55481419; called by muse, mutect2, varscan2
- SMTN | c.424A>G p.R142G | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV60778994; called by muse, mutect2, varscan2
- SPATA32 | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.033); catalogued as COSV59303939; called by muse, mutect2, varscan2
- SQSTM1 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as rs983079876, COSV62434838; called by mutect2, varscan2
- SRGAP1 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV61898358, COSV61898711; called by muse, mutect2, varscan2
- ST8SIA1 | c.287A>T p.K96I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53954590; called by muse, mutect2, varscan2
- TAF5L | c.293C>G p.P98R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51081256; called by muse, mutect2, varscan2
- TGM7 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101476805, COSV71772854; called by muse, mutect2, varscan2
- TLE6 | c.1529C>G p.S510C (on ENST00000246112 / NM_001143986.2; = p.S387C on NM_024760.3) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs767222404, CM1511597, COSV53580365; called by muse, mutect2, varscan2
- TMEM217 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV100362495; called by muse, mutect2
- TRAF1 | c.1006C>G p.L336V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV65868568; called by muse, mutect2, varscan2
- TRPC7 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | catalogued as COSV61458478, COSV61460402; called by muse, mutect2, varscan2
- TTLL13P | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60038118; called by muse, mutect2, varscan2
- TTN | c.43747T>C p.W14583R (on ENST00000591111; = p.W7159R on NM_003319.4) | Missense Mutation (SNP) | VAF 55/180 reads (31%) | PolyPhen probably damaging (0.999); catalogued as rs148549746, COSV60103971; called by muse, mutect2, varscan2
- TTN | c.31624C>G p.P10542A (on ENST00000591111; = p.P9615A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/258 reads (13%) | PolyPhen benign (0.007); catalogued as COSV100636391, COSV60103982; called by muse, mutect2, varscan2
- USP34 | c.4980G>C p.L1660F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV101276797; called by muse, mutect2
- UTRN | c.10286G>C p.R3429T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV62309789; called by muse, mutect2, varscan2
- ZC3H12B | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs759811849, COSV59048502; called by muse, mutect2, varscan2
- ZCWPW1 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as COSV61249229; called by muse, mutect2, varscan2
- ZDBF2 | c.3345A>T p.K1115N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100984471; called by muse, mutect2
- ZFPM2 | c.465G>T p.K155N | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.307); catalogued as COSV68283552; called by muse, mutect2, varscan2
- ZNF101 | c.1100A>T p.E367V | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV58909068; called by muse, mutect2, varscan2
- ZNF208 | c.1891C>T p.H631Y | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV68101066, COSV68107142; called by muse, mutect2, varscan2
- ZNF578 | c.1461G>C p.E487D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); catalogued as COSV101405037; called by muse, mutect2
- ZNF609 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100440548; called by muse, mutect2
- ZNF646 | c.4927G>C p.E1643Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV54924620; called by muse, mutect2, varscan2
- ZNF75D | c.347A>C p.N116T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV66132805; called by muse, mutect2, varscan2
- DGAT1 | c.1000_1005del p.W334_L335del | In Frame Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- HPD | c.241+2_241+22del p.X81_splice | Splice Site (DEL) | VAF 35/69 reads (51%) | called by mutect2, pindel, varscan2
- VRK3 | c.410_430del p.P137_S143del | In Frame Del (DEL) | VAF 8/104 reads (8%) | called by mutect2, pindel
- APOBEC4 | c.921C>A p.G307= | Silent (SNP) | VAF 99/172 reads (58%) | catalogued as COSV58017768; called by muse, mutect2, varscan2
- ASAP1 | c.994C>T p.L332= | Silent (SNP) | VAF 56/434 reads (13%) | catalogued as COSV63044395; called by muse, mutect2, varscan2
- ATP6V1C1 | c.363T>C p.I121= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as COSV67778133; called by muse, mutect2, varscan2
- BIRC6 | c.2286A>G p.Q762= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1225463359, COSV70199943; called by muse, mutect2, varscan2
- EDC3 | c.1308G>C p.R436= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV59340540; called by muse, mutect2, varscan2
- EPG5 | c.4431C>G p.P1477= | Silent (SNP) | VAF 73/248 reads (29%) | catalogued as rs202107707, COSV56350691; called by muse, mutect2, varscan2
- FADS2 | c.726C>G p.G242= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV53899085, COSV99608809; called by muse, mutect2, varscan2
- GK | c.768T>G p.G256= (on ENST00000427190 / NM_001205019.2; = p.G250= on NM_000167.6) | Silent (SNP) | VAF 13/222 reads (6%) | catalogued as COSV100970795; called by muse, mutect2
- HIF1AN | c.321G>A p.K107= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV54500572; called by muse, mutect2, varscan2
- KLK1 | c.516C>T p.L172= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV56827176; called by muse, mutect2, varscan2
- LRP2 | c.171G>T p.A57= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV55543814, COSV55556183; called by muse, mutect2, varscan2
- NRAP | c.5148C>A p.A1716= (on ENST00000359988 / NM_001322945.2; = p.A1681= on NM_006175.4) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV63491028; called by muse, mutect2, varscan2
- PHF24 | c.138C>G p.G46= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV54274720; called by muse, mutect2, varscan2
- PIMREG | c.51C>G p.L17= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV51470985; called by muse, mutect2, varscan2
- PSD2 | c.510C>T p.S170= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs199679832, COSV51201363; called by muse, mutect2, varscan2
- RAD51 | c.810A>G p.V270= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV51111850; called by muse, mutect2, varscan2
- SLC12A4 | c.1692C>T p.I564= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs374992389; called by mutect2, varscan2
- SMG1 | c.4819C>T p.L1607= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV101245670, COSV67171834; called by muse, mutect2, varscan2
- STEAP4 | c.138T>A p.V46= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV57329779; called by muse, mutect2, varscan2
- TNC | c.3918C>T p.G1306= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV60785529; called by muse, mutect2, varscan2
- VWF | c.4587T>C p.D1529= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV99778390; called by muse, mutect2
- WDHD1 | c.3141A>C p.I1047= | Silent (SNP) | VAF 35/231 reads (15%) | catalogued as COSV62214060; called by muse, mutect2, varscan2
- CDX4 | c.*2A>G | 3'UTR (SNP) | VAF 28/154 reads (18%) | catalogued as COSV100999117; called by muse, mutect2, varscan2
- RAB3GAP2 | c.811+1683G>T | Intron (SNP) | VAF 37/232 reads (16%) | catalogued as rs1469346503, COSV52965963; called by muse, mutect2, varscan2
